Somatic mutation profile of tumor specimen TCGA-J7-6720-01A (aliquot TCGA-J7-6720-01A-11D-2136-08) from TCGA case TCGA-J7-6720, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 42.8 years (15,620 days).
Specimen TCGA-J7-6720-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 679b57c6-8c1e-4ac2-aea6-6720d0b18895.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J7-6720-10A (Blood Derived Normal), aliquot TCGA-J7-6720-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cae50f5d-3688-4230-aa6a-9b64b8a84fe6

The open-access MAF lists 40 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 17, Silent 9, Frame Shift Del 5, In Frame Del 3, Splice Site 3, In Frame Ins 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CALCRL | c.274T>C p.F92L | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV66475890; called by muse, mutect2, varscan2
- CDKAL1 | c.655A>G p.T219A | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs780144368, COSV51185808; called by muse, mutect2, varscan2
- COL4A3 | c.2339G>T p.G780V | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM034405, COSV67414846, COSV67416818; called by muse, mutect2, varscan2
- COL6A2 | c.1609-1G>A p.X537_splice | Splice Site (SNP) | VAF 30/90 reads (33%) | catalogued as rs745704771, COSV56009787; called by muse, mutect2, varscan2
- CYP11B1 | c.1122-1G>C p.X374_splice | Splice Site (SNP) | VAF 14/35 reads (40%) | catalogued as COSV52828569; called by muse, mutect2, varscan2
- DGKH | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54935527; called by muse, mutect2, varscan2
- DGKH | c.1175G>T p.G392V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54935549; called by muse, mutect2, varscan2
- FAM135B | c.1111A>G p.T371A | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV52736641; called by muse, mutect2
- LBR | c.1250C>G p.S417C | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55290051; called by muse, mutect2, varscan2
- NOP56 | c.4-5T>A | Splice Region (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100250163; called by muse, mutect2, varscan2
- PCNT | c.3741A>T p.E1247D | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV64030122; called by muse, mutect2, varscan2
- PIAS3 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.347); catalogued as COSV65171670; called by muse, mutect2, varscan2
- PSG2 | c.246T>A p.Y82* | Nonsense Mutation (SNP) | VAF 131/436 reads (30%) | catalogued as COSV68884936; called by muse, mutect2, varscan2
- RELN | c.1784C>G p.T595S | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV59014464; called by muse, mutect2, varscan2
- SBK1 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV59397680; called by muse, mutect2, varscan2
- SFN | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV59433661; called by muse, mutect2, varscan2
- TBC1D14 | c.1892C>A p.T631N | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV68986367; called by muse, mutect2, varscan2
- THBS2 | c.734G>C p.R245P | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.061); catalogued as COSV64680149; called by muse, mutect2, varscan2
- TJAP1 | c.734A>G p.N245S (on ENST00000372445 / NM_001146016.1; = p.N235S on NM_080604.3) | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV52501911; called by muse, mutect2, varscan2
- TSACC | c.34+1G>C p.X12_splice | Splice Site (SNP) | VAF 16/54 reads (30%) | catalogued as COSV55289933; called by muse, mutect2, varscan2
- TWF2 | c.50T>C p.F17S | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59726835; called by muse, mutect2, varscan2
- WDR12 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs771181443, COSV53687714; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1095+1del | Frame Shift Del (DEL) | VAF 33/88 reads (38%) | called by mutect2, pindel, varscan2
- CEMIP | c.2607_2608del p.I869Mfs*7 | Frame Shift Del (DEL) | VAF 45/138 reads (33%) | called by mutect2, pindel, varscan2
- FGD4 | c.1602_1603insTTTTTT p.I534_A535insFF | In Frame Ins (INS) | VAF 32/167 reads (19%) | called by mutect2, pindel, varscan2
- GIN1 | c.77_86del p.S26Cfs*8 | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | called by mutect2, pindel, varscan2
- GPR3 | c.29_49del p.A10_S16del | In Frame Del (DEL) | VAF 43/206 reads (21%) | called by mutect2, pindel, varscan2
- ING4 | c.536del p.G179Afs*31 (on ENST00000396807 / NM_001127582.2; = p.G178Afs*31 on NM_016162.4) | Frame Shift Del (DEL) | VAF 42/166 reads (25%) | called by mutect2, pindel, varscan2
- TTLL12 | c.184_198del p.D62_V66del | In Frame Del (DEL) | VAF 34/215 reads (16%) | called by mutect2, pindel
- ZDHHC14 | c.1088_1098del p.I363Kfs*66 | Frame Shift Del (DEL) | VAF 20/73 reads (27%) | called by mutect2, pindel, varscan2
- ZNF347 | c.2506_2508del p.S836del | In Frame Del (DEL) | VAF 45/160 reads (28%) | called by mutect2, pindel, varscan2
- ACIN1 | c.942A>G p.V314= | Silent (SNP) | VAF 52/174 reads (30%) | catalogued as COSV52978231; called by muse, mutect2
- ADCY4 | c.1947G>T p.L649= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV60255662; called by muse, mutect2
- FBXO36 | c.396A>G p.K132= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV52279182; called by muse, varscan2
- FNDC3B | c.1101C>G p.S367= | Silent (SNP) | VAF 38/128 reads (30%) | catalogued as COSV61045195, COSV61048516; called by muse, mutect2, varscan2
- HINT1 | c.54C>A p.I18= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV58343439; called by muse, mutect2, varscan2
- JKAMP | c.630T>C p.L210= (on ENST00000554271 / NM_001284201.1; = p.L196= on NM_016475.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV54200257; called by muse, mutect2, varscan2
- JPH1 | c.570C>T p.R190= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs777697509, COSV60612399; called by muse, mutect2, varscan2
- SH3RF1 | c.2158T>C p.L720= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV52922433; called by muse, mutect2, varscan2
- TBC1D9B | c.312G>A p.E104= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs1212210143, COSV62282726; called by muse, mutect2, varscan2
